Surgical pathology report (de-identified scan), TCGA case TCGA-06-0195, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0195-01B (Primary Tumor).

[page 1 of 3]
PATHOLOGICAL DIAGNOSIS:

- A. BRAIN, RIGHT FRONTAL LOBE: GLIOBLASTOMA.
- B. BRAIN, RIGHT FRONTAL LOBE: GLIOBLASTOMA.
- C. BRAIN, RIGHT FRONTAL LOBE: GLIOBLASTOMA.

Operation/Specimen: 1&2) Frontal interparietal mass -

Clinical History and Pre-Op Dx: Rt. frontal metastasis.

GROSS PATHOLOGY: Received in two parts.

A. Designated "frontal interparietal mass", is received for intraoperative consultation.

INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: "Glioblastoma"

The specimen consists of two fragments of soft, moist, fleshy dark pink tissue, the larger one measuring approximately 1.1 cm. in greatest diameter, the tissue remaining for frozen section studies are submitted in cassette 1, and the rest of the specimen in cassette 2.

B. Also designated "frontal interparietal mass", was received unfixed and consists of a nodule of soft, moist, somewhat gelatinous pink tissue, measuring 1.4 cm. in greatest diameter. Entirely submitted in cassette 3.

C. Received unfixed and designated as "right frontal lobe", the specimen consists of multiple irregular fragments of soft, gelatinous and partially hemorrhagic light tan tissue, the largest one measures approximately 2.1 cm. in greatest diameter. The fragments are submitted in cassettes 4 thru 9.

MICROSCOPIC: A, B and C. All sections reveal a high grade anaplastic glial tumor. The neoplasm is of high cellularity and is composed of cells that range in differentiation, from small anaplastic cells without discernible cytoplasm to large and pleomorphic multinucleated neoplastic cells. Throughout the tumor there is pronounced nuclear pleomorphism and very brisk mitotic activity. In some of the sections, the neoplastic cells display a vaguely lobular pattern with indistinct clear cytoplasmic halos which may represent differentiation towards oligodendroglioma. The tumor infiltrates diffusely the cerebral cortex and there is evidence of old hemorrhage with macrophages and tumor cells containing hemosiderin in their cytoplasm. There is moderate to pronounced endothelial hyperplasia of stromal vessels and small

[page 2 of 3]
[REDACTED]

microscopic areas of necrosis. Also noted is lymphocytic infiltrate around some stromal blood vessels.

Immunostain for gliofibrillary acidic protein and Ki-67 proliferation marker are pending and an additional report will follow.

[REDACTED]

[REDACTED]

TCGA-06-0195

[page 3 of 3]
[REDACTED]

Glioibrillary acidic protein immunostain shows variable positive staining of the cytoplasm of the neoplastic cells. Immunostain for Ki-67 proliferation marker with monoclonal antibody, MiB-1 reveals a high nuclear labeling index, estimated in 30% of the neoplastic cells.

[REDACTED]

[REDACTED]

TCGA-06-0195

Source: NCI Genomic Data Commons file f2865764-d6a5-49ad-a77e-72d337a9654a (TCGA-06-0195.DCE2B9DD-2598-4E6E-AB0D-707E44F010D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).